MMRF case MMRF_1910 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/083fc59d-32e0-4320-8f67-c8ccbf9ecf77

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 538 days (1.5 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.9 years (22,617 days); ISS stage: II; Days to last known disease status: 538 days (1.5 years); Days to last follow up: 538 days (1.5 years).
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 30 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 16 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 17 days; Days to treatment end: 24 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 25 days; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 53 days; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 53 days; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 53 days; Days to treatment end: 220 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 193 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 332 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 219 days; Days to treatment end: 219 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 333 days; Days to treatment end: 415 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Pomalidomide + Prednisone; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 417 days (1.1 years); Days to treatment end: 487 days (1.3 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 491 days (1.3 years); Days to treatment end: 507 days (1.4 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 512 days (1.4 years); Days to treatment end: 533 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 519 days (1.4 years); Days to treatment end: 533 days (1.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 538.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 23 (ECOG 1): M Protein 4.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27.8 mg/dL; Immunoglobulin G 55.5 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.42 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 66 µmol/L; Blood Urea Nitrogen 4 mmol/L; Calcium 2.02 mmol/L; Albumin 21 g/L; Total Protein 10.1 g/dL; Glucose 5.2 mmol/L; C-Reactive Protein 0.22 mg/dL.
- Day 121 (ECOG 1): M Protein 6.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.027 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 59.8 mg/dL; Immunoglobulin G 78.7 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 5.88 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 6.2 mmol/L; Calcium 1.94 mmol/L; Albumin 32.2 g/L; Total Protein 11.7 g/dL; Glucose 5.9 mmol/L.
- Day 217 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.33 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 1.17 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 4.05 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 56 µmol/L; Blood Urea Nitrogen 5.2 mmol/L; Calcium 2.16 mmol/L; Albumin 28.7 g/L; Total Protein 6.3 g/dL; Glucose 8.4 mmol/L.
- Day 288 (ECOG 1): M Protein 9.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.734 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 42.1 mg/dL; Immunoglobulin G 32.8 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 3.04 µg/mL; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 73 µmol/L; Blood Urea Nitrogen 2.1 mmol/L; Calcium 2.17 mmol/L; Albumin 28 g/L; Total Protein 8.7 g/dL; Glucose 5.8 mmol/L.
- Day 367 (ECOG 1): M Protein 1.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.974 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.11 mg/dL; Immunoglobulin G 21.6 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 89 ×10⁹/L; Creatinine 70 µmol/L; Blood Urea Nitrogen 3 mmol/L; Calcium 2.13 mmol/L; Albumin 35.4 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L.
- Day 478 (ECOG 1): M Protein 3.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.028 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 39.3 mg/dL; Immunoglobulin G 45.9 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 4.72 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 26 ×10⁹/L; Creatinine 60 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.02 mmol/L; Albumin 33.3 g/L; Total Protein 9.1 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day 23: Weight: 91 kg; Height: 174 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1910_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 23 days.
- Sample MMRF_1910_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 23 days.
